Somatic mutation profile of tumor specimen TCGA-DS-A0VK-01A (aliquot TCGA-DS-A0VK-01A-21D-A10S-08) from TCGA case TCGA-DS-A0VK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 46.0 years (16,792 days).
Specimen TCGA-DS-A0VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37eabfb1-278e-4838-b235-6e27b5f3973c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A0VK-10A (Blood Derived Normal), aliquot TCGA-DS-A0VK-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/206878c5-c88e-4a50-8bcc-329e5c86de99

The open-access MAF lists 149 somatic variants for this specimen: 99 protein-altering or splice-affecting, 45 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 45, Nonsense Mutation 5, Intron 3, Frame Shift Del 2, RNA 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 55/137 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- SCN5A | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199473097, CM023672, COSV61126301; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as rs916970760, COSV50139317; called by muse, mutect2, varscan2
- ACAP1 | c.1836C>G p.I612M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV50139340; called by muse, mutect2, varscan2
- ACSL3 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV62484091; called by muse, mutect2, varscan2
- AEBP1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs75175945; called by muse, mutect2, varscan2
- AFF3 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs868486028, COSV57866119; called by muse, mutect2, varscan2
- ARHGAP17 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV51508273; called by muse, mutect2, varscan2
- ATR | c.7115A>C p.D2372A | Missense Mutation (SNP) | VAF 133/484 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV63389856; called by muse, mutect2, varscan2
- BEND3 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs781792490, COSV64681895; called by muse, mutect2, varscan2
- CBLL2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs766786548, COSV60369842; called by muse, mutect2, varscan2
- CCDC85A | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV68154285; called by muse, mutect2, varscan2
- CCNY | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55187541; called by muse, mutect2, varscan2
- CHSY1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV54255221; called by muse, mutect2, varscan2
- CNTRL | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53051349; called by muse, mutect2, varscan2
- COL1A2 | c.3346T>C p.F1116L | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as rs1368149627, COSV51963368; called by muse, mutect2, varscan2
- CST2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV59031623; called by muse, mutect2, varscan2
- CYSLTR1 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64820939; called by muse, mutect2, varscan2
- DCAF16 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as COSV66384113, COSV66384331; called by muse, mutect2, varscan2
- DDX23 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100339851, COSV57285491; called by muse, mutect2, varscan2
- DENND4B | c.4421G>A p.R1474Q | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs573948345, COSV63407196; called by muse, mutect2, varscan2
- DZIP1L | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV59522663; called by muse, mutect2, varscan2
- EFEMP2 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV57261154; called by muse, mutect2, varscan2
- ELAPOR1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752456350, COSV64046269; called by muse, mutect2, varscan2
- ELL | c.1533G>A p.L511= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as rs1359407829, COSV53214686; called by muse, mutect2, varscan2
- EML2 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55602550; called by muse, mutect2, varscan2
- EP400 | c.6713C>T p.P2238L | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57781687; called by muse, mutect2, varscan2
- FAT4 | c.12356C>A p.P4119Q | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1403495139, COSV58701077, COSV58712338; called by muse, mutect2, varscan2
- FLG | c.6292G>A p.E2098K | Missense Mutation (SNP) | VAF 137/406 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.264); catalogued as rs1240887192, COSV64245851; called by muse, mutect2, varscan2
- FLG | c.5468G>T p.G1823V | Missense Mutation (SNP) | VAF 271/864 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64244031, COSV64245856; called by muse, mutect2, varscan2
- GADD45B | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV53126531, COSV53126941; called by muse, mutect2, varscan2
- HEATR5B | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51856748; called by muse, mutect2, varscan2
- HSDL2 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV52716503; called by muse, mutect2, varscan2
- IQCA1 | c.1764C>G p.I588M | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV54502870, COSV54509090; called by muse, mutect2, varscan2
- ITGA7 | c.1463C>T p.S488L (on ENST00000555728; = p.S444L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1330374670, COSV57698928; called by muse, mutect2, varscan2
- ITGAE | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 215/670 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV53997838; called by muse, mutect2, varscan2
- KCNE3 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs547194943, COSV59551401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM6A | c.3337G>A p.V1113I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs367925808, COSV100938566, COSV65039087, COSV65040590, COSV65042618, COSV65043755; called by muse, mutect2, varscan2
- KLHL23 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV55868829; called by muse, varscan2
- KMT2D | c.15257G>A p.R5086Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs775506569, COSV56471245; called by muse, mutect2, varscan2
- LCA5L | c.549G>C p.L183F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV55746692; called by muse, mutect2, varscan2
- LRP2 | c.11757C>G p.H3919Q | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV55566824; called by muse, mutect2, varscan2
- LYL1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53400207, COSV53400559; called by muse, mutect2, varscan2
- MAP3K9 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1266675185, COSV67122441; called by muse, mutect2, varscan2
- MDN1 | c.11536G>C p.E3846Q | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65527587; called by muse, mutect2, varscan2
- MIS18BP1 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV60372490; called by muse, mutect2, varscan2
- MYH14 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV51827346; called by muse, mutect2, varscan2
- MYT1 | c.2247G>C p.E749D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV60510946; called by muse, mutect2, varscan2
- MYT1L | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1489543411, COSV67720855; called by muse, mutect2, varscan2
- NCOR1 | c.3671-1G>A p.X1224_splice | Splice Site (SNP) | VAF 41/103 reads (40%) | catalogued as COSV51988397; called by muse, mutect2, varscan2
- NDST4 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1407918167, COSV52114321; called by muse, mutect2, varscan2
- NF1 | c.2373C>G p.I791M | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV62214092; called by muse, varscan2
- NF1 | c.2573C>A p.S858Y | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV62214105; called by muse, mutect2, varscan2
- NPAS2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs761660915, COSV59560719; called by muse, mutect2, varscan2
- OTUD6A | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV57974112; called by muse, mutect2, varscan2
- PALD1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs368916968; called by muse, mutect2, varscan2
- PC | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as rs1408556921, COSV58993604; called by muse, mutect2, varscan2
- PDGFC | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV56852810; called by muse, mutect2
- PLAU | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV65641908; called by muse, mutect2, varscan2
- PPP1CC | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.416); catalogued as COSV58584605; called by muse, mutect2
- PPP2R1A | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs755649324, COSV59044691; called by muse, mutect2, varscan2
- PRKDC | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1019925698, COSV58059933; called by muse, mutect2
- PSMB8 | c.154G>A p.E52K (on ENST00000374882 / NM_148919.4; = p.E48K on NM_004159.5) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs779815259, COSV62755350; called by muse, mutect2, varscan2
- PSMC2 | c.1191C>G p.I397M | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760946308, COSV53008634; called by muse, mutect2, varscan2
- PSMD2 | c.2662C>T p.L888F | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV59530938; called by muse, mutect2, varscan2
- QPCT | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1340171867, COSV58120495; called by muse, mutect2, varscan2
- RAB36 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54076017; called by muse, mutect2, varscan2
- RP1L1 | c.4978G>A p.E1660K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as rs369627530; called by muse, mutect2, varscan2
- RTN2 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV55594730, COSV55595427; called by muse, mutect2, varscan2
- SBDS | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747312896, COSV55888262; called by muse, mutect2, varscan2
- SEPHS1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 130/283 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59259997; called by muse, mutect2, varscan2
- SERPINB11 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV66957566; called by muse, mutect2
- SGO2 | c.3706G>C p.E1236Q | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV63416823; called by muse, mutect2, varscan2
- SLC36A2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV58864466; called by muse, mutect2, varscan2
- SLC39A5 | c.1021C>A p.Q341K | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as COSV57192985; called by muse, varscan2
- SLC39A5 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57193006; called by muse, varscan2
- SLC6A11 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54391612, COSV54397069; called by muse, mutect2, varscan2
- SLITRK2 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV59427740; called by muse, mutect2
- SMYD4 | c.2364G>T p.M788I | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs749532218, COSV54617000; called by muse, mutect2, varscan2
- SOCS4 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756526707, COSV59461359, COSV59461817; called by muse, mutect2, varscan2
- SSH3 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV57386113; called by muse, mutect2, varscan2
- STAB2 | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66340602; called by muse, mutect2
- TEK | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 132/419 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV66231598; called by muse, mutect2, varscan2
- TMPRSS11A | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV58360254, COSV58361763; called by muse, mutect2, varscan2
- TNNT2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730881123, COSV52663840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPM2 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61407238; called by muse, mutect2, varscan2
- TPR | c.6205C>T p.R2069* | Nonsense Mutation (SNP) | VAF 73/218 reads (33%) | catalogued as COSV66603746; called by muse, mutect2, varscan2
- UBASH3A | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52315082; called by muse, mutect2, varscan2
- UFL1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs778841910, COSV65150397; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3976G>A p.D1326N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54440975; called by muse, mutect2
- UHRF2 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52794971; called by muse, mutect2, varscan2
- ZBTB38 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375255, COSV58543526; called by muse, varscan2
- ZBTB38 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58543533; called by muse, varscan2
- ZBTB38 | c.2932G>C p.E978Q | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV58543540; called by muse, mutect2, varscan2
- ZNF532 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs752804802, COSV60173964; called by muse, mutect2, varscan2
- ZNF875 | c.1232A>G p.K411R | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV60992907; called by muse, mutect2
- MYH7B | c.1998_2001del p.Y666* | Frame Shift Del (DEL) | VAF 72/242 reads (30%) | called by mutect2, pindel, varscan2
- STEAP3 | c.125_144del p.S42Wfs*56 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ZNF84 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ADGRG4 | c.2115G>A p.L705= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV54963400; called by muse, mutect2
- ADRA2A | c.1254G>A p.V418= | Silent (SNP) | VAF 59/212 reads (28%) | catalogued as COSV54529326; called by muse, mutect2, varscan2
- AEBP1 | c.2169C>G p.P723= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV56260019; called by muse, mutect2
- ARMC1 | c.84G>A p.P28= | Silent (SNP) | VAF 82/251 reads (33%) | catalogued as rs140241141; called by muse, mutect2, varscan2
- BBS2 | c.1704C>A p.I568= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as COSV55327887; called by muse, mutect2, varscan2
- CCDC85A | c.1539C>T p.S513= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs747180180, COSV68149890; called by muse, mutect2, varscan2
- CES3 | c.15G>A p.V5= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs762806851, COSV57594782; called by mutect2, varscan2
- CHD1 | c.3246C>T p.F1082= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV52343424; called by muse, mutect2, varscan2
- CHD6 | c.2856G>A p.V952= | Silent (SNP) | VAF 100/365 reads (27%) | catalogued as COSV58560622; called by muse, mutect2, varscan2
- CHRM2 | c.1344G>A p.K448= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as COSV57769065, COSV57780322; called by muse, mutect2, varscan2
- COLGALT1 | c.564C>T p.V188= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV53110816; called by muse, mutect2, varscan2
- DAB2IP | c.643C>T p.L215= (on ENST00000408936; = p.L187= on NM_032552.3) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs267602115, COSV52265141; called by muse, mutect2
- DCLRE1C | c.504C>T p.F168= (on ENST00000378278 / NM_001350965.2; = p.F53= on NM_022487.4) | Silent (SNP) | VAF 164/350 reads (47%) | catalogued as rs61749165, COSV63184815, COSV63185441; called by muse, mutect2, varscan2
- DNAH11 | c.1026G>A p.L342= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV60971849; called by muse, mutect2, varscan2
- DNAH11 | c.9828G>A p.L3276= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV60971862; called by muse, mutect2, varscan2
- FGF21 | c.52C>T p.L18= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as COSV55810955; called by muse, mutect2, varscan2
- FRY | c.4014C>T p.F1338= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV66575972; called by muse, mutect2, varscan2
- GJA9 | c.447C>T p.L149= | Silent (SNP) | VAF 68/227 reads (30%) | catalogued as rs375468847, COSV62532089; called by muse, mutect2, varscan2
- GPR108 | c.1065C>T p.F355= (on ENST00000264080 / NM_001080452.1; = p.F113= on NM_020171.2) | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as COSV51186430; called by muse, mutect2, varscan2
- HERC4 | c.1827G>A p.Q609= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV53273980; called by muse, mutect2, varscan2
- IFT122 | c.3288C>T p.F1096= (on ENST00000348417 / NM_052989.3; = p.F1037= on NM_018262.4) | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as COSV56206437; called by muse, mutect2, varscan2
- KIAA2026 | c.2934G>A p.K978= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs533069462, COSV67356870; called by muse, mutect2, varscan2
- KNTC1 | c.4872G>A p.S1624= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs1223166842, COSV61079447; called by muse, mutect2, varscan2
- LYSMD4 | c.756G>A p.L252= (on ENST00000409796 / NM_001284417.2; = p.L253= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/240 reads (35%) | catalogued as COSV60387321; called by muse, mutect2, varscan2
- MRC1 | c.3042C>G p.V1014= | Silent (SNP) | VAF 192/813 reads (24%) | called by muse, mutect2, varscan2
- MYH13 | c.1296C>T p.A432= | Silent (SNP) | VAF 77/282 reads (27%) | catalogued as rs754560986, COSV52827408; called by muse, mutect2, varscan2
- MYH6 | c.1578G>A p.E526= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV62453232; called by muse, varscan2
- NCAM2 | c.1068C>T p.V356= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as COSV53093936, COSV53109220; called by muse, mutect2, varscan2
- NEB | c.18705C>G p.V6235= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV51443987; called by muse, mutect2, varscan2
- NF1 | c.2193C>T p.L731= | Silent (SNP) | VAF 83/247 reads (34%) | catalogued as COSV62214079; called by muse, mutect2, varscan2
- NRXN1 | c.333C>T p.D111= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1447163289, COSV101276275, COSV68015915; called by muse, mutect2, varscan2
- OR8B8 | c.522C>T p.V174= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV60145341; called by muse, mutect2, varscan2
- PCDH9 | c.960A>G p.R320= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as COSV60558969; called by muse, mutect2, varscan2
- PCDHGA6 | c.1743C>T p.S581= | Silent (SNP) | VAF 95/193 reads (49%) | catalogued as COSV53908205, COSV54055461; called by muse, mutect2, varscan2
- PKN1 | c.396G>A p.E132= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54401711; called by muse, mutect2, varscan2
- POLR1A | c.4563G>A p.E1521= | Silent (SNP) | VAF 72/213 reads (34%) | catalogued as rs1274002761, COSV55697372; called by muse, mutect2, varscan2
- POU6F1 | c.1575G>A p.R525= | Silent (SNP) | VAF 20/456 reads (4%) | catalogued as COSV61327474; called by muse, mutect2
- RASGRF1 | c.3321G>A p.V1107= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV60213153; called by muse, mutect2
- RGL1 | c.1443G>A p.Q481= (on ENST00000360851 / NM_001297672.2; = p.Q516= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as COSV58992254; called by muse, mutect2, varscan2
- RNASEH2C | c.276G>C p.S92= | Silent (SNP) | VAF 62/180 reads (34%) | catalogued as COSV57730316; called by muse, mutect2, varscan2
- RRM2 | c.75C>T p.L25= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV58817468; called by muse, mutect2, varscan2
- SCGB2B2 | c.42G>A p.L14= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV64857297; called by muse, mutect2, varscan2
- SEC24A | c.588G>A p.V196= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV59748895; called by muse, mutect2, varscan2
- SLC35G2 | c.1092C>T p.L364= | Silent (SNP) | VAF 133/582 reads (23%) | catalogued as rs759981904, COSV67588812; called by muse, mutect2, varscan2
- SYNPO2 | c.2038A>C p.R680= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV61114995; called by muse, mutect2
- ADARB2 | c.101-177572C>G | Intron (SNP) | VAF 37/167 reads (22%) | catalogued as COSV67232212; called by muse, mutect2, varscan2
- CHCHD2P9 | n.97C>A | RNA (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- HADH | c.710-824C>T | Intron (SNP) | VAF 127/457 reads (28%) | catalogued as COSV58849539; called by muse, mutect2, varscan2
- LINC01600 | n.864C>G | RNA (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+3422C>T | Intron (SNP) | VAF 70/293 reads (24%) | catalogued as rs778119701, COSV52808920; called by muse, mutect2, varscan2
